Somatic mutation profile of tumor specimen 0DHDZW from CCDI case PBBUKU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 2.0 years (745 days).
Specimen 0DHDZW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 876cb87b-2f6a-48ae-bb84-289f15edf16a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHDZA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e8fabaf-8e02-482d-9ea0-c47d8e9daf46

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H2BW2 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 66/916 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs543811117, COSV54582184; called by muse, mutect2
- WNT3 | c.628G>C p.G210R | Missense Mutation (SNP) | VAF 286/750 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843081; called by muse, mutect2, varscan2
- NCOA6 | c.1022A>T p.N341I | Missense Mutation (SNP) | VAF 463/1123 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- TBXT | c.1305G>A p.M435I | Missense Mutation (SNP) | VAF 367/919 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
